Gene-level copy-number profile of tumor specimen C3N-02089-03 from CPTAC case C3N-02089, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 76.4 years (27,910 days).
Specimen C3N-02089-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 006b5bf2-f9fc-4861-826b-03e3b4b1a103.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02089-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/b786f72c-b661-491b-a99e-3c92329f6c4c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 2,859; copy number 2: 24,691; copy number 3: 20,593; copy number 4: 7,570; copy number 5: 1,904; copy number 6: 944; copy number 7: 212; copy number 8: 9; copy number 9: 89.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:42,209,990–42,210,383, 1 gene: AL031601.1.
- chr14:84,739,942–86,161,500, 12 genes: RNU6-976P, AL163642.1, AL163642.2, AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2, LINC02328, LINC02316.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,158 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,923,337–153,992,155, 14 genes, copy number 6: AL358472.5, DENND4B, CRTC2, SLC39A1, AL358472.7, MIR6737, AL358472.4, AL358472.3, CREB3L4, JTB, AL358472.6, AL358472.2, RAB13, RPS27.
- chr1:159,704,983–161,371,964, 91 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr2:77,652,025–78,290,469, 1 gene, copy number 5 (within-gene range 3–5): AC012494.1.
- chr2:77,915,870–79,185,523, 14 genes, copy number 5 (within-gene range 3–5): LINC01851, AC012494.2, CYCSP6, AC064872.1, AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1.
- chr2:94,575,976–94,751,293, 6 genes, copy number 5: AL845331.2, AL845331.1, CNN2P11, GXYLT1P7, CNN2P8, AC073464.2.
- chr2:94,791,103–97,589,965, 120 genes, copy number 5 (broad region; genes not listed).
- chr2:105,038,069–105,103,036, 2 genes, copy number 8 (within-gene range 4–8): MRPS9, MRPS9-AS1.
- chr2:108,099,110–108,226,331, 3 genes, copy number 8: ACTP1, LINC01594, SETD6P1.
- chr2:140,216,997–140,221,485, 3 genes, copy number 6: MTCO1P44, MTND2P19, MTND1P27.
- chr3:12,287,368–13,283,281, 20 genes, copy number 5: PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022, IQSEC1, AC069271.1.
- chr8:47,089,572–47,198,861, 2 genes, copy number 5 (within-gene range 3–5): AC120036.1, AC120036.5.
- chr8:47,157,118–54,022,456, 91 genes, copy number 5 (broad region; genes not listed).
- chr8:63,136,223–145,066,685, 1,250 genes, copy number 5–6 (broad region; genes not listed).
- chr10:14,518,557–21,293,011, 92 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:42,149,310–42,185,791, 2 genes, copy number 5–6: KSR1P1, IGKV1OR10-1.
- chr10:42,242,721–42,281,819, 2 genes, copy number 6–7: AL031601.2, PABPC1P8.
- chr12:6,199,715–9,845,007, 211 genes, copy number 7 (broad region; genes not listed).
- chr15:78,339,208–101,979,093, 589 genes, copy number 5 (broad region; genes not listed).
- chr17:18,634,247–18,661,950, 4 genes, copy number 8 (within-gene range 3–8): TBC1D28, AC026271.2, AC026271.4, AC026271.1.
- chr18:64,677,796–76,759,866, 134 genes, copy number 5 (broad region; genes not listed).
- chr20:4,422,186–5,197,887, 23 genes, copy number 5: AL139350.1, AL121781.1, AL121916.1, RPS4XP2, PRNP, PRND, PRNT, IDI1P3, AL133396.1, RASSF2, SLC23A2, AL389886.1, AL121890.1, AL121890.3, AL121890.2, AL121890.5, AL121890.4, TMEM230, RNA5SP474, Y_RNA, PCNA, AL121924.1, CDS2.
- chr20:22,054,074–36,746,090, 334 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr20:41,382,383–46,513,559, 150 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 914. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
